Gene-level copy-number profile of tumor specimen TCGA-FF-A7CW-01A from TCGA case TCGA-FF-A7CW, project TCGA-DLBC (Lymphoid Neoplasm Diffuse Large B-cell Lymphoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Diffuse large B-cell lymphoma, NOS; Tissue or organ of origin: Lymph nodes of head, face and neck; Age at diagnosis: 72.6 years (26,520 days).
Specimen TCGA-FF-A7CW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-DLBC.abdcc62d-d5fd-4e50-920c-104bc4fb52a5.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-FF-A7CW-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/7122f11f-a126-4b19-9c9a-5a985e2d89af

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 24; copy number 1: 523; copy number 2: 3,651; copy number 3: 23; copy number 4: 44,045; copy number 5: 34; copy number 6: 8,626; copy number 7: 12; copy number 8: 2,019; copy number 9: 863.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-FF-A7CW-01A-11D-A381-01): tumor purity 0.51, ploidy 2.24, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 24 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:105,403,207–106,325,791, 11 genes (within-gene range 0–2): AL096794.1, LINC02836, Z97206.1, AL591518.1, RN7SKP211, PRDM1, ATG5, AL022067.1, U4, RN7SL47P, RNU6-344P.
- chr9:21,802,636–22,029,594, 2 genes (within-gene range 0–6): MTAP, AL359922.1.
- chr9:21,858,910–22,128,103, 11 genes: AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 863 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr18:20,946,906–80,247,514, 863 genes, copy number 9 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 523. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
